Surgical pathology report (de-identified scan), TCGA case TCGA-MF-A522, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Minnesota, specimen TCGA-MF-A522-01A (Primary Tumor).

[page 1 of 6]
SPECIMEN(S):

A: Lymph node station 7

B: Lymph node, station 7

C: Lymph node, 10 R

D: Lymph node, 10 R #2

E: Lymph node station 10R

F: Lymph node, 10 R #3

G: Lung, right upper lobe bronchial margin

H: Lymph node station 4R

I: Lung wedge biopsy, right middle/lower

ICD-0-3

carcinoma, squamous cell, keratinizing, NOS
8071/3

Site: lung, upper lobe C34.1

hw
10/4/12

FINAL DIAGNOSIS:

G. Lung, right upper lobe, lobectomy

- Histologic tumor type: Invasive squamous cell carcinoma,

keratinizing type

- Histologic grade: Poorly differentiated.

- Tumor size: 5.0 x 4.9 x 3.9 cm

- Angiolymphatic invasion: Absent

- Resection margin (Bronchial and vascular/parenchymal): Free; tumor

closest to the bronchial margin (0.2 cm)

- Tumor involves lobar bronchus

- Visceral pleura involvement: Absent

siPAA Discrepancy		☒

hw
10/4/12

[page 2 of 6]
- Parietal pleura: Not included in the specimen
- Number of lymph nodes in the lobectomy specimen: 5
- Total number of lymph nodes including separately submitted nodes: 12
- Number of lymph nodes involved: 0/12
- Additional findings in uninvolved lung: Obstructive pneumonia, emphysema
- Stage pT2a, N0

A. Lymph node, station 7, excision (including AFS1)

- One lymph node with no evidence of malignancy (0/1)

B. Lymph node, station 7, excision

- One lymph node with no evidence of malignancy (0/1)

C. Lymph node, 10 R, excision: (including CFS1)

- One lymph node with no evidence of malignancy (0/1)

D. Lymph node, 10 R #2, excision: (including DFS1)

- One lymph node with no evidence of malignancy (0/1)

E. Lymph node, station 10 R, excision

- One lymph node with no evidence of malignancy (0/1)

F. Lymph node, 10 R #3, excision: (including FFS1)

- One lymph node with no evidence of malignancy (0/1)

[page 3 of 6]
H. Lymph node, station 4R, excision:

- One lymph node (0/1) with no evidence of metastatic carcinoma.

I. Lung, right middle/lower lobe, wedge biopsy:

- Changes consistent with obstructive with lymphocytic

inflammatory infiltrate.

- No evidence of malignancy

- Emphysema

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

The patient is a year-old man with a history of right lung cancer who undergoes lobectomy with lymph node staging and immediate frozen section diagnosis.

GROSS:

Nine specimens are received, each labeled with the patient's name and hospital identification number.

A. Specimen A is designated "lymph node, station 7." The

[page 4 of 6]
specimen consists of a 2.1 x 1.2 x 0.5 cm red-tan tissue fragment. The specimen is submitted in cassette A for frozen section diagnosis.

B. Specimen B is designated "lymph node, station 7." The specimen consists of a 2.0 x 1.8 x 0.8 cm aggregate of friable, tan-red and irregularly-shaped soft tissue fragments. All fragments are submitted in two cassettes.

C. Specimen C is designated "lymph node, 10 R." The specimen consists of a 0.7 x 0.5 x 0.2 cm segment of adipose tissue. The specimen is submitted in cassette C for frozen section diagnosis.

D. Specimen D is designated "lymph node, 12 R #2." The specimen consists of a red/black tissue fragment measuring 0.8 x 0.5 x 0.4 cm and 0.3 x 0.2 x 0.1 cm. Both fragments are submitted in cassette D for frozen section diagnosis.

E. Specimen E is designated "lymph node station 10 R." The specimen consists of a 0.6 x 0.4 x 0.2 cm tan-red soft tissue fragment. The specimen is submitted in cassette E.

F. Specimen F is designated "lymph node, 10 R #3." The specimen consists of a 1.5 x 1.0 x 0.3 cm tan-gray aggregate of soft tissue. All fragments are submitted in cassette F for frozen section diagnosis.

[page 5 of 6]
G. Specimen G is designated "lung, right upper lobe bronchial margin." The specimen consists of a 263 gm right lower lobectomy measuring 14.3 x 10.2 x 6.0 cm. The pleural surface is remarkable for a underlying mass adjacent to the bronchus. The bronchial margin is removed and submitted enface for frozen section diagnosis. The remainder of the pleural surface is inked blue. The specimen is sectioned revealing an exophytic, tan-white, solid-appearing lesion measuring 5.0 x 4.9 x 3.9 cm. The lesion is adjacent to the hilum and 0.1 cm from the bronchial margin. This lesion appears to abut the serosal surface, where no serosal extension is noted. Sectioning the remainder of the lung parenchyma has a consolidated, tan-red appearance with areas of mucus plugging. No additional mass or lesions are present. Representative tissue was procured for potential future studies. The specimen is sampled in 14 cassettes.

Summary of Cassettes:

G1 - bronchial margin, en face (frozen section).

G2 - three potential lymph nodes.

G3 - single lymph node bisected.

G4 - vascular margin.

G5-G7 - tumor closest to dominant airway.

G8-G11 - additional tumor with adjacent soft tissue.

G12-G14 - uninvolved lung parenchyma.

[page 6 of 6]
H. Specimen H is designated "lymph node station 4 R." The specimen consists of three tan-red, spongy-appearing tissue fragments ranging in size from 2.0 to 0.8 cm in greatest dimension. All fragments are submitted intact in two cassettes.

I. Specimen I is designated "lung wedge biopsy, right middle lower lobe wedge." The specimen consists of a thin, tan-red wedge excision measuring 4.0 x 0.8 x 0.3 cm. The polar surface is submitted intact. The staple line is identified and removed and the new parenchymal margin is inked blue. The specimen is sectioned revealing a spongy, red, unremarkable cut surface. The specimen is entirely submitted in two cassettes.

Summary of Cassettes:

I1-I2 - right middle lower lobe wedge, entirely submitted.

MICROSCOPIC:

Microscopic examination is performed. Permanent sections confirm the frozen section diagnoses.

Source: NCI Genomic Data Commons file f494ed97-e9ec-46c1-ab2c-44f6b24ebb9c (TCGA-MF-A522.E078E483-BF34-41CD-A55A-342E46BD928B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).